Somatic mutation profile of tumor specimen TCGA-ZG-A8QY-01A (aliquot TCGA-ZG-A8QY-01A-11D-A377-08) from TCGA case TCGA-ZG-A8QY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.7 years (24,731 days).
Specimen TCGA-ZG-A8QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba224955-05d9-49ea-8988-4bc1f87e96a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A8QY-10A (Blood Derived Normal), aliquot TCGA-ZG-A8QY-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f65f66f-515e-464b-a21d-dd15b621be03

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Frame Shift Del 5, Splice Site 4, Nonsense Mutation 2, Intron 2, In Frame Del 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.1817A>G p.E606G | Missense Mutation (SNP) | VAF 22/69 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1233687600, COSV101228899; called by muse, mutect2, varscan2
- SPOP | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 42/138 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV61652814, COSV61652918; called by muse, mutect2, varscan2
- AC127029.3 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.664); catalogued as COSV100033305; called by muse, mutect2, varscan2
- ADAM23 | c.925C>G p.H309D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1410602474, COSV100007837; called by muse, mutect2, varscan2
- APRT | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs1347938222, COSV99243230; called by muse, mutect2, varscan2
- BRAF | c.1523T>G p.F508C (on ENST00000288602 / NM_001374244.1; = p.F468C on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as CM060881, COSV56193137, COSV56447994; called by muse, mutect2, varscan2
- BTBD11 | c.1235C>A p.T412N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV99776045; called by muse, mutect2, varscan2
- BTG3 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV100336313; called by muse, mutect2, varscan2
- CHD6 | c.1032C>G p.I344M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100498355, COSV58557233; called by muse, mutect2, varscan2
- CP | c.1713+1G>C p.X571_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99224180; called by muse, mutect2, varscan2
- DCN | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV99272336; called by muse, mutect2, varscan2
- DDX6 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99870429; called by muse, mutect2, varscan2
- DHRS7C | c.724T>C p.W242R (on ENST00000330255 / NM_001220493.2; = p.W241R on NM_001105571.3) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100364745; called by muse, mutect2, varscan2
- FAM83B | c.2737A>G p.T913A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757285314, COSV100174560; called by muse, mutect2, varscan2
- FBN3 | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1164073157, COSV99561105; called by muse, varscan2
- GAD1 | c.665T>C p.F222S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100713842; called by muse, mutect2, varscan2
- GAP43 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759973547, COSV59345075; called by muse, mutect2, varscan2
- GLE1 | c.1646+1G>A p.X549_splice | Splice Site (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100012618; called by muse, mutect2, varscan2
- GLOD4 | c.895A>T p.S299C (on ENST00000301328 / NM_001366247.1; = p.S284C on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100022622; called by muse, mutect2, varscan2
- HSCB | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV99319722; called by muse, mutect2, varscan2
- INSRR | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV63875690; called by muse, mutect2, varscan2
- IRF2BPL | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs1045489697, COSV99468192; called by muse, mutect2, varscan2
- ITPR3 | c.5215G>C p.D1739H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100967483; called by muse, mutect2, varscan2
- MUC17 | c.5024C>A p.A1675D | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as COSV100073711, COSV100075198; called by muse, mutect2, varscan2
- MYOT | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99524959; called by muse, mutect2
- NOA1 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99950560; called by muse, mutect2, varscan2
- PCDHA12 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.116); catalogued as COSV56494202; called by muse, mutect2, varscan2
- PCNX2 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV50887495; called by muse, mutect2, varscan2
- PFKP | c.2123-1G>A p.X708_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as rs1051838115, COSV99829002; called by muse, mutect2
- RASGEF1C | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as rs369386547; called by muse, mutect2, varscan2
- RBFOX1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs754708372, COSV60976264; called by muse, mutect2, varscan2
- SACS | c.3020A>T p.E1007V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs745430192, COSV101207491; called by muse, mutect2, varscan2
- SF3B3 | c.3065T>C p.I1022T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV100209969; called by muse, mutect2, varscan2
- SPHKAP | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as rs201425414, COSV100764174; called by muse, mutect2, varscan2
- SV2B | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100370721; called by muse, mutect2, varscan2
- TANK | c.1208T>C p.F403S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99376224; called by muse, mutect2, varscan2
- TCEAL8 | c.302G>A p.W101* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as COSV100749825; called by muse, mutect2, varscan2
- TDRD6 | c.2890A>C p.K964Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV100287745; called by muse, mutect2, varscan2
- TLR5 | c.2233C>A p.Q745K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1282547180, COSV100643296, COSV60560915; called by muse, mutect2
- ZFAND4 | c.2048+2C>G p.X683_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100762988; called by muse, mutect2, varscan2
- ZNF571 | c.755A>C p.E252A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV100143800; called by muse, mutect2, varscan2
- DDX24 | c.1345_1360del p.W449Kfs*6 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- DLG2 | c.826_838del p.V276Lfs*5 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- H2AC6 | c.145_159del p.P49_A53del | In Frame Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- IFT172 | c.3063_3076del p.K1022Sfs*4 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- KDM6B | c.3443_3449del p.N1148Rfs*2 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- NOA1 | c.620_625del p.A207_L209delinsV | In Frame Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- PCF11 | c.1816del p.S606Afs*14 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- ARHGAP15 | c.1023C>T p.D341= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs138120208; called by muse, mutect2, varscan2
- ATG14 | c.1002T>C p.F334= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99902827; called by muse, mutect2, varscan2
- CFAP74 | c.1554A>G p.K518= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs763119648; called by muse, mutect2, varscan2
- DENND6B | c.669C>T p.S223= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs372514489; called by muse, mutect2, varscan2
- FNIP1 | c.2097A>G p.L699= | Silent (SNP) | VAF 59/216 reads (27%) | catalogued as COSV100330464; called by muse, mutect2, varscan2
- IFT140 | c.684C>T p.S228= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs765361599, COSV101276634, COSV68507444; called by muse, mutect2, varscan2
- KMT2C | c.10467A>G p.Q3489= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as rs1282281845, COSV100072666; called by muse, mutect2, varscan2
- MARK1 | c.810A>G p.L270= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100857302; called by muse, mutect2, varscan2
- PSG3 | c.27C>T p.C9= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as rs776169564, COSV100549022; called by muse, mutect2, varscan2
- RHOU | c.165C>T p.V55= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1419695295, COSV100797176; called by muse, mutect2
- SLC17A8 | c.1353G>T p.G451= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV100035925, COSV60127083; called by muse, mutect2, varscan2
- ZBTB7B | c.1128C>T p.C376= (on ENST00000292176; = p.C410= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs750849996, COSV52694637; called by muse, mutect2, varscan2
- ZCCHC14 | c.669C>G p.T223= (on ENST00000268616; = p.T360= on NM_015144.3) | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs141236185, COSV51889003, COSV99233418; called by muse, mutect2, varscan2
- CDK15 | c.1009+5808A>C | Intron (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99643265; called by muse, mutect2, varscan2
- LINC00173 | n.725C>G | RNA (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- NCOA1 | c.4156-136A>C | Intron (SNP) | VAF 35/139 reads (25%) | catalogued as COSV99946296; called by muse, mutect2, varscan2
- TMCO3 | c.*112C>G | 3'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100952346; called by muse, mutect2, varscan2
